Somatic mutation profile of tumor specimen 0DT69H from CCDI case PBCJAE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.8 years (647 days).
Specimen 0DT69H: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21f2e112-c612-4670-94aa-bfece5b8dcb8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT69A (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5a73e22-d726-4bb0-9327-0642779bebdb

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD163 | c.3199G>A p.A1067T | Missense Mutation (SNP) | VAF 211/980 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs757500485, COSV63131528; called by muse, mutect2, varscan2
- HRNR | c.976G>A p.G326R | Missense Mutation (SNP) | VAF 104/296 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.046); catalogued as rs747884891, COSV100913846, COSV64255415; called by muse, mutect2, varscan2
- LRFN2 | c.537C>A p.S179R | Missense Mutation (SNP) | VAF 30/596 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2
- MYO18B | c.3715G>A p.A1239T | Missense Mutation (SNP) | VAF 35/834 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.081); called by muse, mutect2
- POM121L12 | c.194A>C p.Y65S | Missense Mutation (SNP) | VAF 142/586 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKS1A | c.3402-96del | Intron (DEL) | VAF 19/63 reads (30%) | called by mutect2, pindel, varscan2
- ZCCHC2 | c.-72C>T | 5'UTR (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
